HCMI case HCM-CSHL-0384-D37 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f49e41f1-ab0a-4e6e-9780-2acdb94fa820

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1967; Vital status: Alive.

Diagnoses (1)
1. Tubulovillous adenoma, NOS: ICD-O-3 morphology code: 8263/0; ICD-10 code: D37.4; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: Premalignant; Age at diagnosis: 51.4 years (18,759 days); AJCC staging edition: 8th; AJCC clinical stage: Stage 0; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 58 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 279 days; Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 83.

Molecular and laboratory tests
- MLH1 methylation: Equivocal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 111.1 kg; Height: 187.9 cm; BMI: 32.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0384-D37-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0384-D37-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-CSHL-0384-D37-31B-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 7.
  Slide HCM-CSHL-0384-D37-31B-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 12.
- Sample HCM-CSHL-0384-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0384-D37-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
